Somatic mutation profile of tumor specimen TCGA-EM-A4FK-01A (aliquot TCGA-EM-A4FK-01A-11D-A257-08) from TCGA case TCGA-EM-A4FK, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.9 years (12,383 days).
Specimen TCGA-EM-A4FK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1c038f1-0dc1-43b9-acc8-d03d5b794475.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FK-10A (Blood Derived Normal), aliquot TCGA-EM-A4FK-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e86a6bf9-bea6-42d9-9bd2-6596be1143ef

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 70/183 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.7252A>G p.I2418V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV56360710; called by muse, mutect2, varscan2
- RBM12 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs753301036, COSV58289865; called by muse, mutect2, varscan2
- TNXB | c.10933G>A p.V3645M (on ENST00000647633; = p.V3398M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as rs769706169, COSV64478815; called by muse, mutect2, varscan2
- TTLL8 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99838322; called by muse, mutect2
- UNC79 | c.3562C>T p.P1188S (on ENST00000393151 / NM_001346218.2; = p.P1011S on NM_020818.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.334); catalogued as COSV56379087; called by muse, mutect2, varscan2
- PAPSS1 | c.56_60del p.N19Rfs*69 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, varscan2
- DCHS1 | c.3180A>C p.L1060= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55035417; called by muse, mutect2, varscan2
- HMCN1 | c.618T>C p.N206= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54899693; called by muse, mutect2, varscan2
